Somatic mutation profile of tumor specimen TCGA-06-0686-01A (aliquot TCGA-06-0686-01A-01W-0348-08) from TCGA case TCGA-06-0686, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,503 days).
Specimen TCGA-06-0686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76f79550-6fb0-4c14-994b-83b59fd94a39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0686-10A (Blood Derived Normal), aliquot TCGA-06-0686-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/300211d2-44ab-4a79-a26f-95f05bf4c1a4

The open-access MAF lists 88 somatic variants for this specimen: 71 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Frame Shift Ins 22, Silent 16, Splice Site 2, Splice Region 2, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSCL2 | c.782dup p.I262Hfs*12 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | catalogued as rs749890533; ClinVar: pathogenic; called by mutect2, varscan2
- AC011448.1 | c.44dup p.Y16Lfs*41 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | catalogued as rs751852332; called by pindel, varscan2
- ADAM22 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 296/1494 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.676); catalogued as COSV55977782; called by muse, mutect2, varscan2
- ALLC | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1276153447, COSV52994830; called by muse, mutect2, varscan2
- ALPG | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV54966265; called by muse, mutect2, varscan2
- AP3B1 | c.3032T>C p.I1011T | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54884458; called by muse, mutect2, varscan2
- AQR | c.2610C>A p.D870E | Missense Mutation (SNP) | VAF 30/686 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50040853; called by muse, mutect2
- AREG | c.334dup p.Q112Pfs*7 | Frame Shift Ins (INS) | VAF 18/147 reads (12%) | catalogued as rs757742243; called by mutect2, varscan2
- ARNT2 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 38/1225 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV57582193, COSV57590342; called by muse, mutect2
- AXL | c.874dup p.H292Pfs*47 | Frame Shift Ins (INS) | VAF 18/154 reads (12%) | catalogued as rs778012871; called by mutect2, varscan2
- AZGP1 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 125/672 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV52799334; called by muse, mutect2, varscan2
- BMP15 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 199/245 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53140591; called by muse, mutect2, varscan2
- C14orf39 | c.1349dup p.F451Vfs*4 | Frame Shift Ins (INS) | VAF 11/91 reads (12%) | catalogued as rs776870689; called by mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 98/301 reads (33%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2, varscan2
- CCNE2 | c.549T>G p.N183K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV57376182; called by muse, mutect2, varscan2
- CDKN2A | c.407dup p.T137Hfs*5 | Frame Shift Ins (INS) | VAF 11/106 reads (10%) | catalogued as rs749588877; ClinVar: uncertain significance; called by mutect2, pindel
- CFAP161 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV54429392; called by muse, mutect2, varscan2
- CFAP74 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs766114699, COSV54568567; called by muse, mutect2, varscan2
- CLMN | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54180818; called by muse, mutect2
- COL14A1 | c.4472G>A p.R1491Q | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs142082215, COSV99921277; called by muse, mutect2, varscan2
- CTNND2 | c.2642C>T p.S881L | Missense Mutation (SNP) | VAF 184/386 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs777753200, COSV58891714; called by muse, mutect2, varscan2
- CXCR4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV54016139, COSV54017107; called by muse, mutect2
- DENND2C | c.1013C>A p.A338E | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.111); catalogued as COSV67923976; called by muse, mutect2
- FRYL | c.6394-2A>G p.X2132_splice | Splice Site (SNP) | VAF 39/71 reads (55%) | catalogued as COSV51961707; called by muse, mutect2, varscan2
- GABRG2 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 270/652 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV62718371; called by muse, mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 11/91 reads (12%) | catalogued as rs754177800; called by mutect2, varscan2
- GJA5 | c.795dup p.D266Rfs*3 | Frame Shift Ins (INS) | VAF 16/178 reads (9%) | catalogued as rs782537868; called by mutect2, pindel
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | catalogued as rs749150409; called by mutect2, varscan2
- GRIK1 | c.781-1G>A p.X261_splice | Splice Site (SNP) | VAF 9/288 reads (3%) | catalogued as COSV58731337; called by muse, mutect2
- HHIPL2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV58565417; called by muse, mutect2, varscan2
- IL15RA | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 120/163 reads (74%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66092730; called by muse, mutect2, varscan2
- INHBE | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 787/858 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1458340123, COSV56988215, COSV99875352; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 34/180 reads (19%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 40/229 reads (17%) | catalogued as rs757410385; called by mutect2, varscan2
- LSS | c.1527dup p.H510Afs*18 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs1335748816; called by pindel, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 11/74 reads (15%) | catalogued as rs765962881; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 25/136 reads (18%) | catalogued as rs777328830; called by mutect2, varscan2
- MUC16 | c.38255G>A p.R12752K | Missense Mutation (SNP) | VAF 370/929 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.824); catalogued as COSV67491719; called by muse, varscan2
- MYH11 | c.2339A>G p.E780G | Missense Mutation (SNP) | VAF 55/702 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55568873; called by muse, mutect2
- NEK3 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51619298; called by muse, mutect2, varscan2
- NPY5R | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs754248718, COSV58452143; called by muse, mutect2, varscan2
- OR2H1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 127/382 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759165826, COSV65810709; called by muse, mutect2, varscan2
- OR4S2 | c.909T>A p.N303K | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56747048; called by muse, mutect2, varscan2
- PDGFRB | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758280032, COSV55805130; called by muse, mutect2, varscan2
- PHYH | c.683dup p.V229Sfs*2 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs767403321; called by pindel, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 40/342 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PLS1 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 14/508 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV61835429; called by muse, mutect2
- PPIC | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs371579770, COSV100120614; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 70/548 reads (13%) | catalogued as rs778683789; called by mutect2, varscan2
- RBBP6 | c.4540A>C p.K1514Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV60505355; called by muse, mutect2, varscan2
- RBMXL1 | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 103/241 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV53101521; called by muse, mutect2, varscan2
- RBPJL | c.272dup p.P92Afs*44 | Frame Shift Ins (INS) | VAF 10/96 reads (10%) | catalogued as rs761146769; called by mutect2, pindel, varscan2
- SAMD9L | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 96/1805 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV59085053; called by muse, mutect2
- SLC12A2 | c.3314A>G p.E1105G | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1470718426, COSV52471699; called by muse, mutect2, varscan2
- SNAP47 | c.423T>A p.H141Q | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59919988; called by muse, mutect2
- SUN3 | c.579A>T p.G193= | Splice Region (SNP) | VAF 84/461 reads (18%) | catalogued as COSV52053853; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 58/362 reads (16%) | catalogued as rs763321097; called by mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 14/69 reads (20%) | catalogued as rs782753958; called by mutect2, varscan2
- TGFA | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 75/170 reads (44%) | catalogued as rs782253342, COSV54913863; called by muse, mutect2, varscan2
- TIE1 | c.1942dup p.R648Pfs*52 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | catalogued as rs749393189; called by pindel, varscan2
- TRIML1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60194468; called by mutect2, varscan2
- TTN | c.66985C>T p.R22329W (on ENST00000591111; = p.R14905W on NM_003319.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | PolyPhen probably damaging (0.999); catalogued as rs748041610, COSV59932620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28889T>G p.F9630C (on ENST00000591111; = p.F8703C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/436 reads (39%) | PolyPhen possibly damaging (0.487); catalogued as COSV60330856; called by muse, mutect2, varscan2
- ZNF23 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV61841006; called by muse, mutect2, varscan2
- ZNF493 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62750185; called by muse, mutect2, varscan2
- ZSCAN5A | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs762073087, COSV54231584; called by muse, mutect2, varscan2
- GPR37L1 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- LRRC73 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPPL2C | c.229dup p.H77Pfs*24 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by pindel, varscan2
- TRPV6 | c.1485del p.F496Lfs*20 | Frame Shift Del (DEL) | VAF 26/201 reads (13%) | called by mutect2, pindel, varscan2
- ZNF106 | c.2338C>G p.Q780E | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ABCA8 | c.666T>A p.T222= | Silent (SNP) | VAF 347/896 reads (39%) | catalogued as rs1048344720, COSV52202227; called by muse, mutect2, varscan2
- CHD7 | c.7470G>A p.S2490= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as rs780608336, COSV101418378, COSV71111008; called by muse, mutect2, varscan2
- CYP4F3 | c.456G>A p.T152= | Silent (SNP) | VAF 110/309 reads (36%) | catalogued as rs138865516; called by muse, mutect2, varscan2
- EEFSEC | c.651G>T p.T217= | Silent (SNP) | VAF 34/593 reads (6%) | called by muse, mutect2
- ENPP2 | c.2523G>A p.K841= (on ENST00000075322 / NM_001040092.3; = p.K893= on NM_006209.5) | Silent (SNP) | VAF 399/1048 reads (38%) | catalogued as COSV50011824, COSV50015989; called by mutect2, varscan2
- GHSR | c.207G>A p.S69= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs995230051, COSV53838664, COSV53838892, COSV53839470; called by muse, mutect2, varscan2
- GPR150 | c.726C>T p.V242= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV66168594; called by muse, mutect2, varscan2
- ISLR | c.1245G>C p.L415= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV51433946; called by muse, mutect2, varscan2
- KCNB2 | c.1998G>A p.T666= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs1277870040, COSV73050439, COSV73051069; called by muse, mutect2, varscan2
- KCNRG | c.33G>C p.V11= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV53949672; called by muse, mutect2, varscan2
- LARGE2 | c.543A>C p.L181= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV57654352; called by muse, mutect2, varscan2
- OR5M8 | c.171C>A p.P57= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100510693; called by muse, mutect2
- OR6F1 | c.426G>A p.A142= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs373540517; called by muse, mutect2, varscan2
- PDE1C | c.1425G>A p.S475= | Silent (SNP) | VAF 209/876 reads (24%) | catalogued as rs763131623, COSV58515001; called by muse, mutect2, varscan2
- SGCG | c.318A>G p.Q106= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as rs371622125; called by mutect2, varscan2
- ZNF184 | c.378A>C p.I126= | Silent (SNP) | VAF 66/202 reads (33%) | catalogued as COSV53004394; called by muse, mutect2, varscan2
- SNORD114-20 | n.6C>T | RNA (SNP) | VAF 152/401 reads (38%) | catalogued as rs1369080429; called by muse, mutect2, varscan2
